Gene-level copy-number profile of tumor specimen TCGA-V1-A9Z7-01A from TCGA case TCGA-V1-A9Z7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ca00f265-ef84-4070-a169-1e4ddbc74a74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9Z7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/391fde4c-e2b9-40fa-89f7-90c8352478dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 296; copy number 1: 8,547; copy number 2: 48,684; copy number 3: 1,442; copy number 4: 420; copy number 5: 6; copy number 6: 220; copy number 7: 190; copy number 10: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9Z7-01A-11D-A41J-01): tumor purity 0.59, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 269 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:22,345,071–22,611,063, 3 genes (within-gene range 0–1): ADGRA3, AC098583.1, AC098583.2.
- chr4:22,727,375–22,727,950, 1 gene: CDC42P6.
- chr5:98,853,985–103,212,799, 52 genes: CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1, AC114324.2, AC114324.1, GUSBP8, LINC02113, AC008837.1, AC008837.2, CRLF3P2, EEF1A1P20, Y_RNA, MTCYBP22, MTND6P22, MTND5P10, MTND4P35, MTND4LP5, MTND3P19, MTCO3P22, MTATP6P2, MTCO2P22, MTCO1P22, GUSBP7, RNU6-1119P, AC113385.3, AC113385.2, AC113385.1, AC021086.1, FAM174A, AC027315.1, RN7SKP62, ST8SIA4, MIR548P, RN7SL802P, OR7H2P, AC117525.1, RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1, PPIP5K2.
- chr5:104,917,492–105,246,364, 2 genes: AC091987.1, RAB9BP1.
- chr5:106,415,576–107,011,052, 4 genes: AC027313.1, AC114940.1, AC114940.2, LINC01950.
- chr20:18,011,955–26,251,546, 207 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 427 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,326,575–47,736,306, 205 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:48,008,415–52,460,959, 50 genes, copy number 7 (within-gene range 2–7): UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1.
- chr8:52,722,903–53,162,987, 4 genes, copy number 7: AC113139.1, NPBWR1, AC009800.1, AC009646.1.
- chr8:59,760,047–60,136,599, 4 genes, copy number 6–7 (within-gene range 2–7): AC107934.1, AC107934.2, AC022709.1, AC021393.1.
- chr8:124,811,042–134,881,899, 147 genes, copy number 6 (broad region; genes not listed).
- chr16:78,099,430–79,212,667, 1 gene, copy number 5 (within-gene range 1–10): WWOX.
- chr16:78,355,529–79,110,882, 16 genes, copy number 5–10: LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3, AC009141.1, RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2.

Autosomal genes at a single copy (total copy number 1): 6,198. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
